Surgical pathology report (de-identified scan), TCGA case TCGA-DU-5871, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-5871-01A (Primary Tumor).

[page 1 of 4]
Taken: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

=====

CLINICAL HISTORY

[REDACTED], [REDACTED]

and has

a large (5 to 6 cm) left frontal heterogeneous enhancing lesion with some mass effect and vasogenic edema.

OPERATIVE DIAGNOSES

Brain tumor

Operation/Specimen: A: Brain, left frontal tumor, biopsy

B: Brain, left frontal enhancing lesion on MRI, biopsy

C: Brain, left frontal tumor, biopsy

PATHOLOGICAL DIAGNOSIS:

A and B. Brain, left frontal, excisional biopsies:

1. Mixed oligoastrocytoma, with atypical features.

2. MIB-1 proliferation index: 3%.

See Microscopy Description and Comment.

COMMENT

The tumor is a moderately cellular glial neoplasm that has a mixed oligoastrocytic phenotype, predominantly astrocytic. There is moderate

nuclear pleomorphism. Mitotic figures are found with difficulty, and the

MIB-1 proliferation index is low at about 3% in the more active areas. There

is not microvascular cellular proliferation or necrosis.

The glioma is somewhat cellular and has nuclear pleomorphism.

However, there

are not anaplastic features, i.e. brisk mitotic activity, necrosis, or microvascular cellular proliferation. The atypical cellular features portend

a heightened biological potential, which in addition to the focal enhancement

on imaging studies suggest on going anaplastic transformation of the neoplasm.

The features in the biopsy may be correlated with clinical, imaging, and

operative findings for their final interpretation and patient's follow up.

Electronically Signed Out

[REDACTED]

[page 2 of 4]
PROCEDURES/ADDENDA

Loss of Heterozygosity 1p, 19q Assay

Date Ordered: Date Reported:

Interpretation

NEGATIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is NOT detected.

Informative loci are: D1S548, D1S1592, D1S552, D19S219, D19S412

Results-Comments

Testing performed on DNA extracted from tumor paraffin tissue block and a corresponding blood specimen for germline comparison.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers

on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as

backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C

(with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4

nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the

first line markers at that chromosome arm are uninformative or otherwise

ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a

stand-alone diagnostic test. This test was developed and its performance

characteristics determined by the laboratory as required by regulations. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in

the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample

may preclude the detection of allelic loss.

Electronically Signed Out

Date Ordered: Date Reported:
Interpretation

[page 3 of 4]
POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on paraffin tissue block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter

have been shown to benefit from therapy with alkylating agents.

Assessment of

MGMT promoter methylation status involves bisulfite treatment of DNA followed

by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

FDA COMMENT: The above data are not to be construed as the results from a

stand alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] laboratory as required by [REDACTED]. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in

the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

[REDACTED]
PCR for EGFR variant III mutation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE - No evidence of EGFRvIII mutation is detected

Results-Comments

TEST DESCRIPTION: Testing performed on RNA extracted from tissue paraffin block

The epidermal growth factor receptor (EGFR) is an attractive molecular target

in glioblastoma because it is amplified, overexpressed, and/or mutated in up

to 40% to 50% of patients. Epidermal growth factor receptor variant III

(EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is

commonly expressed in glioblastoma. Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct

subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been

shown to sensitize tumors to EGFR tyrosine kinase inhibitors when the tumor

suppressor protein PTEN is intact. RNA is extracted from formalin fixed,

paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is

[page 4 of 4]
then amplified using standard PCR technique for DNA templates. PCR products

are detected by gel electrophoresis. The limit of detection of this assay has

been determined to be approximately 5 mutant cells in 100 normal cells.

FDA Comment: The above data are not to be construed as the results from a

stand alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] laboratory as required by [REDACTED]. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in

the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

[REDACTED]

=====

Source: NCI Genomic Data Commons file 16145ce4-1a0f-4f09-832d-2e3c4273c041 (TCGA-DU-5871.FC11347A-6C78-46ED-A07D-46D44A165260.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).